FM case AD12807 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/d9b68956-e74a-418f-9e1f-ed1edc57a15a

Female, 40.2 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the thyroid gland; metastasis biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
